Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A70A, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A70A-01A (Primary Tumor).

Surgical Pathology

Final Results

Surgical Pathology

Final

CASE NUMBER:

DIAGNOSIS:

Adrenal gland, right (adrenalectomy):

- Pheochromocytoma, 5.5 cm.

NOTE: The tumor cells are arranged in well-defined nests bound by a delicate fibrovascular stroma. They vary in size and shape and have a finely granular purplish to amphophilic cytoplasm. The nuclei of tumor cells are round to oval with conspicuous nucleoli. Immunohistochemical staining is performed on section "1B"; lesional cells of the pheochromocytoma stain positive for synaptophysin, while the sustentacular cells stain positive for S-100. Attached to the pheochromocytoma is the adrenal gland with unremarkable adrenal cortical tissue.

CLINICAL INFORMATION: Brief Clinical History: woman with pheochromocytoma Specimen

Taken For Protocol: 01 - Yes Requestor Name downey Requestor

Phone/Pager: Admitting Protocol Number:

PROCEDURE: Pre-Operative Diagnosis: pheochromocytoma Post-Operative

Diagnosis:

adrenal mass Operative Findings: ~5 cm R adrenal mass

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, RIGHT, With tumor

GROSS DESCRIPTION: Received fresh from the OR labeled with the patient's name, medical record number and "right adrenal with tumor perm and Research" is an adrenalectomy specimen that measures overall 5.5 x 4.3 x 4.8 cm and weighs 62.0 gram. The specimen consists of tumor and normal-appearing adrenal gland. The nodule is incised to reveal a firm, homogeneous, gray, cut surface with small areas of hemorrhage. Approximately 5.0 cc of tumor and 1.0 cc of normal adrenal gland are procured for Research. As per surgeon, no margins are required. The procurement was performed by

The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen is received and is consistent with the above description. It is serially sectioned and representative sections are submitted in white cassettes labeled for permanent processing.

Gross dictated by

Source: NCI Genomic Data Commons file 5bf8afec-fbd9-4129-8adf-137656fa10c6 (TCGA-QR-A70A.88515273-97BE-44EF-A7BE-8942E1C44A7A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).